Surgical pathology report (de-identified scan), TCGA case TCGA-33-AASB, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-33-AASB-01A (Primary Tumor).

[page 1 of 3]
=====

INTERPRETATION AND DIAGNOSIS:

1. LUNG, LEFT UPPER LOBE (LOBECTOMY): INFILTRATING POORLY DIFFERENTIATED NON-SMALL CELL CARCINOMA (4.5 CM). THE TUMOR INVOLVES A LARGE AIRWAY. THE TUMOR DOES NOT INVOLVE THE PLEURA. ANGIOLYMPHATIC INVASION IS IDENTIFIED. VASCULAR AND BRONCHIAL MARGINS AS WELL AS SEVEN (7) HILAR LYMPH NODES ARE NEGATIVE FOR TUMOR. SEE NOTE. *Per TSS pathologist, tumor is 100% squamous cell carcinoma*

2. LYMPH NODE, LEVEL V (BX.): ONE (1) LYMPH NODE, NEGATIVE FOR TUMOR.

3. LYMPH NODE, LEVEL VI (BX.): FIVE (5) LYMPH NODES, NEGATIVE FOR TUMOR.

4. LYMPH NODE, LEVEL VIII (BX.): ONE (1) LYMPH NODE AND ASSOCIATED FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR. *Per TSS - 0% glandular.*

NOTE: The carcinoma has both squamous and glandular features. The pathologic stage is T2N0MX. This case was reviewed at the

*Electronic signature

=====

Clinical History:
LUNG MASS

GROSS DESCRIPTION

(Continued on next page.)

ICD-O-3

Carcinoma, squamous cell NOS 8070/3

Site: @ Lung, upper lobe C34.1
Jt 5/28/14

[page 2 of 3]
SURGICAL
PATHOLOGY

PART #1: LEFT UPPER LOBE
Resident Pathologist:

The specimen is received fresh labeled [REDACTED] and designated "Left upper lobe". The specimen consists of a grossly recognizable left upper lobectomy specimen measuring 25.5 x 15 x 7.5 cm. It weighs 480 grams. There is a palpable mass in the apex of the upper lobe adjacent to the hilum. There is associated pleural puckering. Sectioning reveals tan-white slightly lobulated mass measuring 4.5 cm in diameter. It is located approximately 0.5 cm from the pleural surface. The tumor directly abuts a segmental bronchus extending into the apex. It appears to encase the bronchus but not penetrate through it. The hilar margins however appear grossly negative. No grossly positive hilar lymph nodes are identified. Sectioning through the remaining lung reveals firm parenchyma with mucus plugging. No satellite nodules are identified. Representative sections are submitted.

This specimen is harvested by the Tumor Bank.

SUMMARY OF SECTIONS

- 1 - A - 1 (SHAVE VASCULAR MARGINS)
- 1 - B - 1 (SHAVE BRONCHIAL MARGINS)
- 1 - C - 1 (PERPENDICULAR SECTION THROUGH APICAL SEGMENTAL BRONCHUS INVOLVING TUMOR)
- 1 - D - 1 (TUMOR TO HILAR PLEURA)
- 1 - E - 1 (TUMOR TO PARIETAL PLEURA)
- 3 - F-H - 1 EACH (TUMOR)
- 1 - I - M (HILAR LYMPH NODES)
- 1 - J - 2 (NORMAL LUNG)
- 10 - TOTAL - M

(Continued on next page.)

[page 3 of 3]
SURGICAL
PATHOLOGY

PART #2: LEVEL 5
Resident Pathologist:

The specimen is received in formalin labeled [REDACTED] and designated "Level V". It consists of an aggregate of fibrofatty soft tissue measuring 2 x 0.5 x 0.5 cm. There is a grossly recognizable lymph node measuring 2 x 0.6 x 0.5 cm. It is bisected and submitted in its entirety in a single cassette.

SUMMARY OF SECTIONS

- 1 - A - 2 (BISECTED NODE)
- 1 - TOTAL - 2

PART #3: LEVEL 6 LYMPH NODE
Resident Pathologist:

The specimen is received in formalin labeled [REDACTED] and designated "Level VI lymph node". The specimen consists of multiple anthracotic tan-brown lymph nodes, approximately four in number. They are submitted in their entirety in a single cassette.

SUMMARY OF SECTIONS

- 1 - TOTAL - M
- 1 - TOTAL - M

PART #4: LEVEL 8
Resident Pathologist:

The specimen is received in formalin labeled [REDACTED] and designated "Level VIII". The specimen consists of one grossly recognizable lymph node measuring 0.9 x 0.4 x 0.3 cm. It is bisected and submitted in its entirety in a single cassette.

SUMMARY OF SECTIONS

- 1 - A - 2
- 1 - TOTAL - 2

(End of Report)

printed

Source: NCI Genomic Data Commons file cbb6fc00-7add-4fa1-a9e2-68f50ccc9fc0 (TCGA-33-AASB.DF569855-8AF0-4930-97CC-8A65CA697106.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).